Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A3IZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A3IZ-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Sentinel lymph node #1, excision:
Rare isolated cytokeratin positive cells (pN0i+).
B. Right breast, resection:
Invasive lobular carcinoma, 2.6 cm, extending to involve the inferior and lateral margins.

Microscopic Description:

Microscopic examination performed.

- A. Sentinel lymph nodes examined at multiple levels section and H&E staining as well as immunohistochemistry for pan-keratin. No metastasis is seen on H&E staining. On pancytokeratin stain there are rare isolated cytokeratin positive cells (pN0i+).
B. The following template applies to the right breast:

Invasive Carcinoma:

Histologic type: Invasive lobular cancer

Histologic grade:

Overall grade: 2
Architectural score: 3
Nuclear score: 2
Mitotic score: 1

Greatest dimension (pT): 2.6 cm, pT2

Specimen margins: Positive, invasive cancer extends to the inferior margin, (green ink) in B1 and B3 and the lateral margin, (yellow ink) B7

Vessel invasion: Not identified

Calcification: Present

Ductal carcinoma in situ: not identified

Description of non-tumorous breast: Biopsy site changes

Comments: None

Prognostic markers: Previously performed

Specimen

- A. Sentinel node #1 -
B. Right breast(single long stitch lateral, double stitch anterior)

Clinical Information

Right breast cancer

Gross Description

- A. Container A is labeled with the patient's name, medical record number and "sentinel node #1". The specimen container holds a single rubbery tan lymph node measuring 1.2 x 1 x 0.8 cm. It is bisected and submitted in blocks A1 and A2.

1CB-0-3
carcinoma, infiltrating lobular, NOS
Site: breast, NOS c50.9 8520/3
lw 12/8/11

[page 2 of 2]
B. Container B is labeled with the patient's name, medical record number and "right breast - single long lateral, double stitch anterior". The specimen is inked as follows blue - anterior; left - posterior; yellow - lateral; orange - medial; red-tan superior; green - inferior. The specimen measurements are 8.7 x 7.5 x 5.2 cm in greatest dimensions. The specimen is serially sectioned. Near the inferior lateral surgical margin there is a tumor mass which is more palpable than visible and measures 2.6 x 2.2 x 1.5 cm. Biopsy site changes are evident. This mass appears to extend close to the inferior margin. Tissue is obtained for tissue procurement. Representative sections are submitted in B1-B14.

60 12/8/11

Source: NCI Genomic Data Commons file db9e92e5-57c4-4bf4-b2d2-0394c101f441 (TCGA-A7-A3IZ.90F83655-038B-412C-91BD-84CC3A4201D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).